Gene-level copy-number profile of tumor specimen TCGA-44-6144-01A from TCGA case TCGA-44-6144, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 58.3 years (21,283 days).
Specimen TCGA-44-6144-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.0bd49a1c-166b-4039-a578-50e3828130a2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-44-6144-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/329c6806-a25b-4922-a074-fd27f63918c8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 15,090; copy number 2: 29,973; copy number 3: 10,441; copy number 4: 3,028; copy number 5: 478; copy number 6: 753; copy number 7: 51.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-44-6144-01A-11D-1752-01): tumor purity 0.54, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,282 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,859,912–38,965,038, 1 gene, copy number 7 (within-gene range 2–7): AL139260.1.
- chr1:38,864,501–46,316,776, 265 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr8:82,979,411–145,066,685, 975 genes, copy number 5–6 (within-gene range 1–6) (broad region; genes not listed).
- chr10:49,154,725–50,816,495, 41 genes, copy number 5 (within-gene range 4–5): TMEM273, C10orf71-AS1, C10orf71, DRGX, AL138760.1, ERCC6, HMGB1P50, CHAT, SLC18A3, C10orf53, OGDHL, MAPK6P6, RPL21P89, PARG, RPL35AP24, TIMM23B, TIMM23B-AGAP6, SNORA74C-2, RNA5SP317, AL442003.1, AGAP6, FAM21EP, SLC9A3P3, WASHC2A, SLC9A3P1, ASAH2, DYNC1I2P1, SGMS1, AC069547.2, AC069547.1, AL117341.1, RNU7-107P, SGMS1-AS1, SHQ1P1, BEND3P1, NUTM2HP, AL589794.1, CTSLP4, PGGT1BP1, AL589794.2, ASAH2B.

Autosomal genes at a single copy (total copy number 1): 12,669. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
